Somatic mutation profile of tumor specimen TCGA-E6-A2P9-01A (aliquot TCGA-E6-A2P9-01A-11D-A19Y-09) from TCGA case TCGA-E6-A2P9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 65.9 years (24,088 days).
Specimen TCGA-E6-A2P9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55a1d9b3-c05a-44a0-9192-0357b5c95aab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E6-A2P9-10A (Blood Derived Normal), aliquot TCGA-E6-A2P9-10B-01D-A19Y-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9723d0e7-8513-4cf9-9df6-e62b84ee3c94

The open-access MAF lists 1,108 somatic variants for this specimen: 813 protein-altering or splice-affecting, 260 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 547, Silent 260, Frame Shift Del 168, Frame Shift Ins 41, Nonsense Mutation 34, Intron 15, Splice Site 13, 3'UTR 7, RNA 7, Splice Region 5, In Frame Del 5, 3'Flank 3.

Variants (750 of 1,108; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as rs575001023, CM031620, COSV100752544; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs202160435, COSV53723910, COSV53729033; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 14/28 reads (50%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- KMT2D | c.9265dup p.V3089Gfs*9 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | catalogued as rs1333678798; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 9/60 reads (15%) | catalogued as rs781585299; ClinVar: pathogenic; called by pindel, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 23/48 reads (48%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- RAPSN | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121909257, CM080516, COSV100100029; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.15dup p.D6Rfs*49 | Frame Shift Ins (INS) | VAF 17/65 reads (26%) | catalogued as rs756055465; called by mutect2, pindel, varscan2
- AADACL4 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as rs147107256; called by muse, mutect2, varscan2
- AANAT | c.559A>G p.T187A | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754158557, COSV99166187; called by muse, mutect2, varscan2
- ABCA13 | c.12857G>A p.R4286Q | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs374724171; called by muse, mutect2, varscan2
- ABCA5 | c.4808C>A p.A1603E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.895); catalogued as rs759412787, COSV52220441, COSV99288078; called by muse, mutect2, varscan2
- AC008397.2 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100828200; called by muse, mutect2, varscan2
- ACAA2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99551743; called by muse, mutect2, varscan2
- ACSL4 | c.281A>G p.D94G (on ENST00000340800 / NM_022977.2; = p.D53G on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.206); catalogued as rs770302078, COSV61614178; called by muse, mutect2, varscan2
- ACTN4 | c.181A>C p.N61H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99399855; called by muse, mutect2, varscan2
- ACVR1B | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231305; called by muse, mutect2, varscan2
- ADAMTS3 | c.2974C>A p.L992I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99710433; called by muse, mutect2, varscan2
- ADAMTS9 | c.1943A>G p.D648G | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99898914; called by muse, mutect2
- ADGRA1 | c.686del p.G229Afs*4 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as COSV101658625; called by mutect2, varscan2
- ADGRG1 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as CM138003, COSV101113370; called by muse, mutect2, varscan2
- ADHFE1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.097); catalogued as rs148191690; called by muse, mutect2, varscan2
- AGO2 | c.791-1G>T p.X264_splice | Splice Site (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99595351; called by muse, mutect2
- AGPAT4 | c.907del p.R303Gfs*7 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | catalogued as rs750826126, COSV57248889; called by mutect2, pindel, varscan2
- AICDA | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99984059; called by muse, mutect2, varscan2
- AKT1S1 | c.488G>C p.G163A (on ENST00000344175 / NM_001098633.4; = p.G183A on NM_032375.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs754890149, COSV59274365; called by muse, mutect2, varscan2
- AL645922.1 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV100190818; called by muse, mutect2, varscan2
- ALG5 | c.712T>A p.F238I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99523541; called by muse, mutect2, varscan2
- ALOX15B | c.1793A>C p.N598T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV101205581; called by muse, mutect2, varscan2
- AMBRA1 | c.1773C>G p.Y591* (on ENST00000458649 / NM_001367468.1; = p.Y501* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100093074, COSV54050394; called by muse, mutect2, varscan2
- AMBRA1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100093078; called by muse, mutect2, varscan2
- ANGPT2 | c.700del p.I234* | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs34047276; called by mutect2, varscan2
- ANK2 | c.6658G>A p.E2220K | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.385); catalogued as COSV100000228; called by muse, mutect2, varscan2
- ANKK1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1184934502, COSV100392731; called by muse, mutect2, varscan2
- ANKLE2 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100513973; called by muse, mutect2, varscan2
- ANKRD13C | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs747979372, COSV99256384; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1760G>T p.R587M | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100628434; called by mutect2, varscan2
- ANKRD27 | c.1735G>A p.G579S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); catalogued as COSV100042616; called by muse, mutect2, varscan2
- ANO1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs748825788, COSV100303751; called by muse, mutect2, varscan2
- ANO10 | c.269_270del p.K90Rfs*4 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as rs775536114; called by mutect2, pindel, varscan2
- ANO5 | c.88-1G>A p.X30_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100201533; called by muse, mutect2, varscan2
- ANXA2 | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.678); catalogued as rs1803909, COSV100221921; called by muse, mutect2, varscan2
- ANXA9 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.823); catalogued as COSV100929070; called by muse, mutect2
- AOC2 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1172689768, COSV53828761; called by muse, mutect2, varscan2
- APLP1 | c.1784C>T p.S595F (on ENST00000221891 / NM_001024807.3; = p.S594F on NM_005166.4) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99697557; called by muse, mutect2, varscan2
- APOBEC3D | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.97); catalogued as COSV99328831; called by muse, mutect2, varscan2
- ARHGEF10 | c.425G>T p.G142V (on ENST00000398564; = p.G118V on NM_014629.4) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.026); catalogued as rs768925210, COSV100034089; called by muse, mutect2, varscan2
- ARHGEF18 | c.1645G>A p.E549K (on ENST00000359920 / NM_001130955.2; = p.E445K on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs768741771, COSV100149157; called by muse, mutect2
- ARHGEF3 | c.1496C>T p.T499M | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.38); catalogued as rs771018864, COSV56332822; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | catalogued as rs758608743; called by mutect2, varscan2
- ARID5B | c.698C>A p.T233N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99689196; called by muse, mutect2, varscan2
- ARMC3 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99957637; called by muse, mutect2, varscan2
- ARMC5 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV99192360; called by muse, mutect2, varscan2
- ARPP21 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99491285; called by muse, mutect2, varscan2
- ARVCF | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs563696635, COSV99599016; called by muse, mutect2, varscan2
- ASB6 | c.850G>T p.G284* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV99475631; called by muse, mutect2, varscan2
- ASL | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564735357, COSV100508833; called by muse, mutect2, varscan2
- ASXL1 | c.2467T>G p.L823V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.041); catalogued as COSV100038056; called by muse, mutect2, varscan2
- ATF6 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as COSV100909057; called by muse, mutect2, varscan2
- ATP12A | c.342del p.F115Sfs*28 | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as rs35191129; called by mutect2, varscan2
- ATP1A1 | c.74A>G p.K25R | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55191611, COSV55194897, COSV99814238; called by muse, mutect2, varscan2
- ATP2A1 | c.1657G>T p.G553C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100837130; called by muse, mutect2, varscan2
- ATP7B | c.1675T>A p.Y559N | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99666145; called by muse, mutect2, varscan2
- ATP9B | c.2987C>T p.P996L | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1304072135, COSV100303068, COSV100304112; called by muse, mutect2, varscan2
- B4GALNT4 | c.918dup p.R307Afs*98 | Frame Shift Ins (INS) | VAF 15/50 reads (30%) | catalogued as rs770737105; called by mutect2, varscan2
- BCL11B | c.659G>A p.S220N (on ENST00000357195 / NM_001282237.2; = p.S149N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV100595254, COSV61733498; called by muse, mutect2, varscan2
- BCL9 | c.2704G>T p.A902S | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.98); PolyPhen benign (0.048); catalogued as COSV99324650; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 19/40 reads (48%) | catalogued as rs752427670; called by mutect2, varscan2
- BMP15 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV99399255; called by muse, mutect2, varscan2
- BMPR2 | c.690del p.V231Cfs*21 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as COSV65810054; called by mutect2, pindel, varscan2
- BRCA2 | c.41T>A p.I14N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs1241704385, COSV100563892; called by muse, mutect2, varscan2
- BRIP1 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99369555; called by muse, mutect2, varscan2
- BROX | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100572085; called by muse, mutect2, varscan2
- BUB1B | c.1501G>A p.V501I | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99806653; called by muse, mutect2, varscan2
- C19orf54 | c.962C>T p.T321I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV99648525; called by muse, mutect2, varscan2
- C1GALT1C1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.711); catalogued as rs761999635, COSV100485578; called by muse, mutect2
- C1QTNF1 | c.748C>A p.L250I | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs1302607980, COSV100189752; called by muse, mutect2
- C5 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs767070451, COSV56324677; called by muse, mutect2, varscan2
- C9orf50 | c.1105T>C p.F369L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs1332400888, COSV100992308; called by muse, mutect2, varscan2
- CACNA1E | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100701452; called by muse, mutect2, varscan2
- CACNA1H | c.3719C>T p.A1240V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV100671152; called by muse, mutect2, varscan2
- CACNA1S | c.2831G>A p.C944Y | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100754759; called by muse, mutect2
- CAPN5 | c.1013C>T p.T338I (on ENST00000456580; = p.T298I on NM_004055.5) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.464); catalogued as rs566712391, COSV99581860; called by muse, mutect2, varscan2
- CARD10 | c.1578del p.S527Vfs*31 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs35832225; called by mutect2, pindel, varscan2
- CARS2 | c.657G>A p.A219= | Splice Region (SNP) | VAF 17/39 reads (44%) | catalogued as rs375938059, COSV99959725; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCAR2 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.762); catalogued as rs527350374, COSV100414551; called by muse, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC158 | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.475); catalogued as COSV101187173; called by muse, mutect2, varscan2
- CCDC160 | c.935C>A p.T312K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.039); catalogued as rs377317260, COSV100892092; called by muse, varscan2
- CCDC171 | c.3544C>A p.L1182M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV99900021; called by muse, mutect2, varscan2
- CCDC190 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1172264943, COSV100905808; called by muse, mutect2, varscan2
- CCDC40 | c.783_784del p.R261Sfs*7 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs757076408; called by pindel, varscan2
- CCDC8 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.373); catalogued as COSV100281930; called by muse, mutect2, varscan2
- CCDC8 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV100281931; called by muse, mutect2, varscan2
- CCIN | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as rs368073473, COSV58724976; called by muse, mutect2, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 54/88 reads (61%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDC14A | c.1420A>C p.S474R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs770987278, COSV100324593; called by muse, mutect2, varscan2
- CDH11 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 30/70 reads (43%) | catalogued as COSV99217520; called by muse, mutect2, varscan2
- CDH16 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as rs971619864, COSV100233701, COSV55340243; called by muse, mutect2, varscan2
- CDHR2 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs772459663, COSV56136608, COSV99991169; called by muse, mutect2, varscan2
- CDRT1 | c.1087C>A p.R363S | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as rs761493902, COSV55410996, COSV99887504; called by muse, mutect2, varscan2
- CEBPE | c.836del p.G279Vfs*19 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | catalogued as rs1363394381, COSV52829926; called by mutect2, pindel, varscan2
- CELSR2 | c.3482C>T p.P1161L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs774502637, COSV99603272; called by muse, mutect2, varscan2
- CEMIP | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.943); catalogued as rs750368243, COSV99586282; called by muse, varscan2
- CEP85L | c.418del p.E140Sfs*6 | Frame Shift Del (DEL) | VAF 22/70 reads (31%) | catalogued as rs776770568, COSV63826036; called by mutect2, pindel, varscan2
- CHD1 | c.4244G>A p.S1415N | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.966); catalogued as rs147154039; called by muse, mutect2, varscan2
- CHD5 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746309035, COSV99312802; called by muse, mutect2, varscan2
- CHD6 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs759159347, COSV58561023; called by muse, mutect2, varscan2
- CHEK1 | c.240A>C p.Q80H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV54023183, COSV99629532; called by muse, mutect2, varscan2
- CHERP | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); catalogued as COSV99550060; called by muse, mutect2, varscan2
- CHL1 | c.2749G>A p.E917K (on ENST00000397491 / NM_001253387.1; = p.E933K on NM_006614.4) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV99850414; called by muse, mutect2, varscan2
- CHM | c.1584_1587del p.V529Hfs*7 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs587776746; called by pindel, varscan2
- CHPF2 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99222882; called by muse, mutect2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 18/74 reads (24%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRM4 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as rs780553103, COSV100708753; called by muse, mutect2, varscan2
- CHST10 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as rs148953500; called by muse, mutect2, varscan2
- CHST12 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1254761720, COSV99324353; called by muse, mutect2, varscan2
- CHSY1 | c.666del p.P223Lfs*3 | Frame Shift Del (DEL) | VAF 20/53 reads (38%) | catalogued as rs762321510; called by mutect2, pindel, varscan2
- CIBAR1 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100844635, COSV63897917; called by muse, mutect2, varscan2
- CIC | c.3262G>C p.G1088R | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV99359144; called by muse, mutect2, varscan2
- CLASP2 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs754123905, COSV56288167; called by muse, mutect2, varscan2
- CLN8 | c.613A>T p.M205L | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.373); catalogued as COSV100485994; called by muse, mutect2, varscan2
- COG8 | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV99650656; called by muse, mutect2, varscan2
- COL15A1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100897494; called by muse, mutect2, varscan2
- COL15A1 | c.1870C>A p.P624T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100897496; called by muse, varscan2
- COL24A1 | c.4409C>T p.P1470L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV100993020; called by muse, mutect2, varscan2
- COL5A2 | c.2357G>T p.G786V | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs887892854, COSV66409773; called by muse, mutect2, varscan2
- COL5A2 | c.1774G>A p.A592T | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.869); catalogued as rs930995205, COSV66407403, COSV66412351; called by muse, mutect2, varscan2
- CORO2B | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs535068266, COSV99962985; called by muse, mutect2, varscan2
- CPNE3 | c.779G>A p.S260N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1390211369, COSV99547295; called by muse, mutect2, varscan2
- CPS1 | c.3479A>G p.Q1160R | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.044); catalogued as COSV51814707, COSV99242399; called by muse, mutect2, varscan2
- CRCP | c.178C>T p.H60Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1419742908, COSV100647722; called by muse, mutect2, varscan2
- CREB5 | c.401C>T p.A134V (on ENST00000357727 / NM_182898.4; = p.A127V on NM_004904.3) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100744298; called by muse, mutect2, varscan2
- CRYM | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1280853209, COSV99561625; called by muse, mutect2, varscan2
- CTC1 | c.2470C>A p.P824T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.675); catalogued as COSV100236215; called by muse, mutect2, varscan2
- CXCR6 | c.53G>A p.S18N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs771852091, COSV99945294; called by muse, mutect2, varscan2
- CYB561A3 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.119); catalogued as COSV99582303; called by muse, mutect2, varscan2
- CYP4F11 | c.1163G>A p.S388N | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930686; called by muse, mutect2, varscan2
- CYP4F2 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.19); catalogued as COSV55617176; called by muse, mutect2
- CYP4F3 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.19); catalogued as rs769603208, COSV99657896; called by muse, mutect2, varscan2
- DAAM2 | c.2225C>T p.A742V | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV51421544; called by muse, mutect2, varscan2
- DAB1 | c.532A>C p.K178Q | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV100139651, COSV100139744; called by muse, mutect2, varscan2
- DACT1 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs370918124; called by muse, mutect2
- DBN1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1390363072, COSV52788072; called by muse, mutect2, varscan2
- DCAF8L1 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs770928929, COSV71595462, COSV71595570; called by muse, mutect2, varscan2
- DCTN1 | c.539G>A p.S180N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs1365948671, COSV100720881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDC | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1285477390, CM155193, COSV100779145; called by muse, mutect2, varscan2
- DDR2 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.806); catalogued as COSV100906114; called by muse, mutect2, varscan2
- DDX3X | c.742G>A p.E248K (on ENST00000399959; = p.E249K on NM_001356.5) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs752738546, COSV67864121; called by muse, mutect2, varscan2
- DDX52 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 27/53 reads (51%) | catalogued as rs576442612; called by muse, mutect2, varscan2
- DEFB110 | c.20del p.F7Sfs*25 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs772119246; called by mutect2, pindel, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | catalogued as rs553532837; called by mutect2, varscan2
- DENND4C | c.5396A>G p.E1799G (on ENST00000434457 / NM_001330640.2; = p.E1750G on NM_017925.7) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100727345; called by muse, mutect2, varscan2
- DGCR2 | c.613G>T p.V205L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99593382; called by muse, mutect2, varscan2
- DHRS1 | c.593C>T p.T198I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99852214; called by muse, mutect2, varscan2
- DHX9 | c.2169C>A p.N723K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100841279; called by muse, mutect2, varscan2
- DIP2B | c.4357C>T p.R1453C | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.988); catalogued as rs769646567, COSV99998068; called by muse, mutect2, varscan2
- DIP2C | c.4357C>T p.R1453W | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs547773637, COSV55165245; called by muse, mutect2, varscan2
- DIRAS3 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100921304; called by muse, mutect2, varscan2
- DIS3L2 | c.1895T>C p.V632A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV56047425; called by muse, mutect2, varscan2
- DLL1 | c.1004G>T p.S335I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV100815958, COSV64538890; called by muse, mutect2, varscan2
- DNAH1 | c.7031G>C p.G2344A | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs368682985; called by muse, mutect2, varscan2
- DNAH2 | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs765692580, COSV101208998, COSV66726799; called by muse, mutect2, varscan2
- DNAH2 | c.3373G>A p.V1125I | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101209079; called by muse, mutect2, varscan2
- DNAH5 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99446185; called by muse, mutect2, varscan2
- DNER | c.2125G>A p.A709T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as COSV100518564; called by muse, mutect2, varscan2
- DNM1 | c.1342C>T p.Q448* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV100359611; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 35/89 reads (39%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK7 | c.3542G>A p.R1181H (on ENST00000635253 / NM_001367561.1; = p.R1150H on NM_033407.3) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs766018011, COSV52015874; called by muse, mutect2, varscan2
- DPYSL5 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.17); catalogued as rs139435744; called by muse, mutect2, varscan2
- DRG1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as COSV100513617; called by muse, mutect2, varscan2
- DSCAML1 | c.2866C>T p.R956W (on ENST00000321322; = p.R896W on NM_020693.4) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV100355027; called by muse, mutect2, varscan2
- DTX4 | c.1188del p.K396Nfs*34 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs1381179969; called by mutect2, varscan2
- DUSP12 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100909684; called by muse, mutect2, varscan2
- DVL1 | c.224G>A p.G75D | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101127327; called by muse, mutect2, varscan2
- EAPP | c.374dup p.K126Efs*10 | Frame Shift Ins (INS) | VAF 20/54 reads (37%) | catalogued as rs1257825851; called by mutect2, varscan2
- ECPAS | c.2123C>T p.A708V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99397713; called by muse, mutect2, varscan2
- EDC4 | c.677G>A p.G226D | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs751438933, COSV99534281; called by muse, mutect2, varscan2
- EIF2A | c.641C>G p.A214G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV99855809; called by muse, mutect2, varscan2
- EIF3B | c.1085del p.G362Efs*28 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as COSV62803535; called by mutect2, pindel, varscan2
- EIF3I | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV100557125; called by muse, mutect2, varscan2
- ELF4 | c.1021del p.Q341Rfs*30 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as COSV57452819, COSV57454138; called by mutect2, pindel, varscan2
- ELL3 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs766111308, COSV100082495; called by muse, mutect2, varscan2
- EMSY | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100595499; called by muse, mutect2, varscan2
- ENDOV | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369225866; called by muse, mutect2, varscan2
- ENOX1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs771833542, COSV54898059, COSV54914777; called by muse, mutect2, varscan2
- EP300 | c.5828C>T p.A1943V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.978); catalogued as COSV99607722; called by muse, mutect2, varscan2
- EPC1 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs200404179; called by muse, mutect2, varscan2
- EPG5 | c.6146A>G p.Y2049C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); catalogued as COSV99956692; called by muse, mutect2, varscan2
- EPHA2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765981383, COSV100626040, COSV64453977; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs756461692; called by mutect2, varscan2
- ERAP1 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV99700728; called by muse, mutect2, varscan2
- ERMP1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.548); catalogued as rs777428417, COSV53036978; called by muse, varscan2
- ESRP1 | c.1214C>T p.T405I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100619211; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 36/68 reads (53%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRP2 | c.1061G>A p.R354Q (on ENST00000565858 / NM_001365264.1; = p.R344Q on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.354); catalogued as rs1033623250, COSV99251151; called by muse, mutect2, varscan2
- ESRRA | c.700C>T p.R234* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99134489; called by muse, mutect2, varscan2
- ESYT2 | c.1535C>T p.A512V (on ENST00000613624; = p.A436V on NM_020728.3) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.143); catalogued as rs1227510268, COSV99275981; called by muse, mutect2, varscan2
- ETV4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV100081587; called by muse, mutect2, varscan2
- EXT2 | c.1438C>T p.P480S (on ENST00000343631; = p.P513S on NM_000401.3) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1183076518, COSV100640531; called by muse, mutect2, varscan2
- EZR | c.1579G>A p.V527M | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as COSV99791649; called by muse, mutect2, varscan2
- FAM110B | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64063065; called by muse, mutect2
- FAM20A | c.811A>G p.R271G | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99873234; called by muse, mutect2, varscan2
- FAM214B | c.124del p.A42Rfs*25 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as rs746881923; called by mutect2, pindel, varscan2
- FAM222B | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.237); catalogued as COSV100368270; called by muse, mutect2, varscan2
- FAM24A | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100925069, COSV64405905; called by muse, mutect2, varscan2
- FAM47C | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs182976429; called by muse, mutect2, varscan2
- FAM81B | c.1102C>G p.Q368E | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs756787447, COSV51981394; called by muse, mutect2, varscan2
- FAM91A1 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100593475; called by muse, mutect2, varscan2
- FANCM | c.2165A>G p.Q722R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV99950639; called by muse, mutect2, varscan2
- FASN | c.3694G>T p.V1232L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60752013; called by muse, mutect2, varscan2
- FAT1 | c.10167G>T p.R3389S | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.99); PolyPhen benign (0.044); catalogued as COSV101499145; called by muse, mutect2, varscan2
- FAT3 | c.4964C>T p.A1655V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); catalogued as COSV53097187, COSV99963050; called by muse, mutect2, varscan2
- FAT4 | c.12218C>T p.A4073V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.987); catalogued as COSV100627554; called by muse, mutect2, varscan2
- FBXO21 | c.1744G>A p.V582M (on ENST00000330622 / NM_033624.3; = p.V575M on NM_015002.3) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs758989840, COSV100401633; called by muse, mutect2, varscan2
- FCRL3 | c.1300G>T p.G434* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100942937, COSV63841783; called by muse, mutect2, varscan2
- FGF7 | c.535del p.T179Rfs*15 | Frame Shift Del (DEL) | VAF 80/215 reads (37%) | catalogued as rs777372807; called by mutect2, varscan2
- FLG | c.8398T>C p.Y2800H | Missense Mutation (SNP) | VAF 74/655 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100910912; called by muse, mutect2, varscan2
- FLNB | c.4441G>A p.V1481I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs563226585, COSV99912122; called by muse, mutect2
- FMO5 | c.1340C>A p.P447H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99566777; called by muse, mutect2
- FRA10AC1 | c.694del p.R232Efs*96 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs775948504; called by mutect2, varscan2
- FRAS1 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV99349237; called by muse, mutect2, varscan2
- FRMD4B | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as rs1252748095, COSV68329700; called by muse, mutect2, varscan2
- FSIP2 | c.16778C>T p.T5593I | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV100554358; called by muse, varscan2
- GABRG2 | c.1139C>A p.S380Y (on ENST00000361925 / NM_001375343.1; = p.S340Y on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729386, COSV62718810; called by muse, mutect2, varscan2
- GALNT2 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.059); catalogued as rs1370421490, COSV64197740; called by muse, mutect2, varscan2
- GANAB | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs751022869, COSV100399500, COSV57953565; called by muse, mutect2, varscan2
- GATA5 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99435697; called by muse, mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 24/63 reads (38%) | catalogued as rs754177800; called by mutect2, varscan2
- GDPD5 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.231); catalogued as COSV100409132; called by muse, mutect2, varscan2
- GGNBP2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1351337757; called by muse, mutect2, varscan2
- GGT7 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as COSV100321801; called by muse, mutect2, varscan2
- GGTLC2 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1480930429, COSV101312192; called by muse, mutect2, varscan2
- GHR | c.1813C>T p.Q605* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs1561257474, COSV100050064; called by muse, mutect2, varscan2
- GIGYF2 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV101004019, COSV101004085; called by muse, mutect2, varscan2
- GLG1 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs752956876, COSV99215427; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 12/36 reads (33%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGA2 | c.2615A>T p.E872V | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100359616; called by muse, mutect2, varscan2
- GON4L | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99673696; called by muse, mutect2, varscan2
- GPER1 | c.910del p.L304Sfs*16 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | catalogued as rs776379860; called by mutect2, pindel, varscan2
- GRAMD1C | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs550686355, COSV100822803; called by muse, mutect2, varscan2
- GRIK4 | c.1809del p.F604Sfs*27 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | catalogued as COSV70801839; called by mutect2, pindel, varscan2
- GRIN2B | c.1789G>T p.G597* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as rs1555110866, COSV101662948; called by muse, mutect2
- GRIP2 | c.1156G>A p.G386R (on ENST00000619221; = p.G289R on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375130319, COSV99817043; called by muse, mutect2, varscan2
- GRIP2 | c.1076C>T p.S359L (on ENST00000619221; = p.S262L on NM_001080423.4) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1383596093, COSV56124831, COSV99817045; called by muse, mutect2, varscan2
- GRM7 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63129838; called by muse, mutect2
- GSE1 | c.1933C>A p.P645T | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV99496175; called by muse, mutect2, varscan2
- GTF3C1 | c.3241G>A p.A1081T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.133); catalogued as rs1355997727, COSV100649073; called by muse, mutect2, varscan2
- GUCY2F | c.1180A>G p.M394V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99484640; called by muse, mutect2, varscan2
- HAS1 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV99708259; called by muse, mutect2, varscan2
- HAUS5 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.186); catalogued as rs1403477459, COSV99177974; called by muse, mutect2
- HAVCR1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100208036; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as COSV55172930; called by mutect2, varscan2
- HCCS | c.609G>A p.G203= | Splice Region (SNP) | VAF 16/31 reads (52%) | catalogued as rs1198387862, COSV100335636; called by muse, mutect2, varscan2
- HDAC10 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs771709435, COSV99352183; called by muse, mutect2, varscan2
- HEATR5B | c.5179A>G p.M1727V | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs746930556, COSV99248595; called by muse, mutect2, varscan2
- HECTD4 | c.4285G>A p.V1429I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100295891; called by muse, mutect2, varscan2
- HELZ2 | c.6616dup p.R2206Pfs*42 (on ENST00000467148 / NM_001037335.2; = p.R1637Pfs*42 on NM_033405.3) | Frame Shift Ins (INS) | VAF 8/15 reads (53%) | catalogued as rs745497383; called by mutect2, varscan2
- HEXD | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100027613; called by muse, mutect2, varscan2
- HGS | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as COSV100230306; called by muse, mutect2, varscan2
- HLA-DOA | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100008125; called by muse, mutect2, varscan2
- HLF | c.297del p.S100Afs*106 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as COSV56830780; called by mutect2, pindel, varscan2
- HNRNPM | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs773146380, COSV99725328; called by muse, mutect2, varscan2
- HOXA9 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777202871, COSV100604349; called by muse, mutect2, varscan2
- HPGD | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV99640205; called by muse, mutect2, varscan2
- HRH4 | c.341T>C p.L114P | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99907759; called by muse, mutect2, varscan2
- HS6ST1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs769535275, COSV99389433; called by muse, mutect2, varscan2
- HS6ST2 | c.1544A>G p.Q515R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.039); catalogued as COSV100897054; called by muse, mutect2, varscan2
- HSDL1 | c.953A>T p.N318I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.442); catalogued as COSV99550294; called by muse, mutect2
- HSPA9 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99785290; called by muse, mutect2, varscan2
- HSPB1 | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.223); catalogued as COSV99949155; called by muse, mutect2, varscan2
- HSPB9 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs781941486, COSV99863428, COSV99863715, COSV99863719; called by muse, mutect2, varscan2
- HTATSF1 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as COSV54481145, COSV99511449; called by muse, mutect2, varscan2
- HTT | c.7505C>T p.A2502V | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61866573; called by muse, mutect2, varscan2
- HTT | c.9202T>C p.W3068R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100750538; called by muse, mutect2, varscan2
- IDI2 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1394382532, COSV99479136; called by muse, mutect2, varscan2
- IGDCC4 | c.3448C>A p.L1150I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV100732737; called by muse, mutect2, varscan2
- IGHV3-48 | c.102del p.S36Pfs*2 | Frame Shift Del (DEL) | VAF 26/73 reads (36%) | catalogued as rs1222627364; called by mutect2, pindel, varscan2
- IL4I1 | c.1474A>G p.T492A | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as COSV99680482; called by muse, mutect2, varscan2
- INHA | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99216399; called by muse, mutect2, varscan2
- INKA2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs751736006, COSV61878738; called by muse, mutect2, varscan2
- INO80 | c.766C>A p.H256N | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100731619; called by muse, mutect2, varscan2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs762875806; called by mutect2, varscan2
- INPP4A | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as rs1559033620, COSV50811540, COSV99302166; called by muse, mutect2, varscan2
- INPP4A | c.2219G>T p.R740M (on ENST00000074304 / NM_001134224.1; = p.R701M on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99302854; called by muse, mutect2, varscan2
- INPP5A | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100704192; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INTS1 | c.2335C>T p.P779S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV101247560; called by muse, mutect2, varscan2
- INTS10 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV67603699; called by muse, mutect2, varscan2
- INTS6L | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV100878039; called by muse, mutect2, varscan2
- IRS4 | c.1772dup p.K592Qfs*12 | Frame Shift Ins (INS) | VAF 24/47 reads (51%) | catalogued as rs780982673; called by mutect2, varscan2
- IRX2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57411026; called by muse, varscan2
- ISG20L2 | c.865del p.L289Sfs*15 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as rs761558950, COSV57459436; called by mutect2, varscan2
- ITGA2B | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as COSV99288644; called by muse, mutect2, varscan2
- ITGAL | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757861462, COSV100776114; called by muse, mutect2, varscan2
- ITGAV | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs554897868, COSV53708763; called by muse, mutect2, varscan2
- ITSN1 | c.4504G>A p.D1502N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773094165, COSV67157597; called by muse, mutect2, varscan2
- JRK | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs781863311, COSV101401061; called by muse, mutect2
- KAT6B | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.15); catalogued as rs370657796; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KBTBD2 | c.1347G>A p.W449* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100406425; called by muse, mutect2, varscan2
- KCNA5 | c.1540G>A p.V514I | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs1172712297, COSV52904278, COSV52905346, COSV52907390; called by muse, mutect2, varscan2
- KCNC3 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as rs543411553, COSV100979196; called by muse, mutect2, varscan2
- KCNK2 | c.1174G>A p.E392K (on ENST00000444842 / NM_001017425.3; = p.E377K on NM_014217.4) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs759536206, COSV101222034, COSV67202918; called by muse, mutect2, varscan2
- KCNT2 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99652157; called by muse, mutect2, varscan2
- KCTD8 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100759261; called by muse, mutect2, varscan2
- KDF1 | c.429del p.S144Afs*104 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as COSV57671558; called by mutect2, pindel, varscan2
- KEAP1 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99407450, COSV99408053; called by muse, mutect2
- KIAA0100 | c.1771+2T>C p.X591_splice | Splice Site (SNP) | VAF 5/19 reads (26%) | catalogued as COSV101197244; called by muse, mutect2, varscan2
- KIAA0100 | c.151del p.W51Gfs*77 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs1339576763; called by mutect2, pindel, varscan2
- KIAA0753 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs773610474, COSV63817343; called by muse, mutect2, varscan2
- KIAA1522 | c.947G>A p.R316H (on ENST00000373480 / NM_001198972.2; = p.R375H on NM_020888.3) | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1353411253, COSV53866155; called by muse, mutect2, varscan2
- KIAA1755 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99641626; called by muse, mutect2, varscan2
- KIF13B | c.3863del p.K1288Rfs*13 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs1287634008; called by mutect2, pindel, varscan2
- KIF20A | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99136669; called by muse, mutect2, varscan2
- KIF24 | c.3536C>T p.T1179M | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs781559463, COSV52658222; called by muse, mutect2, varscan2
- KIF5C | c.1850G>A p.R617K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV101276102; called by muse, mutect2, varscan2
- KIZ | c.1412C>A p.T471N | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.408); catalogued as COSV99851907; called by muse, mutect2, varscan2
- KLC2 | c.1708del p.Q570Rfs*8 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | catalogued as rs1183967253, COSV57581594; called by mutect2, pindel
- KLHL18 | c.129G>T p.K43N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as COSV99230613; called by muse, mutect2, varscan2
- KLHL20 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.969); catalogued as COSV99268210; called by muse, mutect2, varscan2
- KLK1 | c.629G>A p.C210Y | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100032585; called by muse, mutect2, varscan2
- KMT2E | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV99995946; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 30/53 reads (57%) | catalogued as rs764099275; called by mutect2, varscan2
- KRT27 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as rs748955660, COSV100053197; called by muse, mutect2, varscan2
- KRT78 | c.429G>A p.W143* | Nonsense Mutation (SNP) | VAF 21/46 reads (46%) | catalogued as rs756539697, COSV100467163; called by muse, mutect2, varscan2
- KRTAP21-1 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs539276998, COSV100624906; called by muse, mutect2, varscan2
- KSR1 | c.833G>A p.R278Q (on ENST00000644974 / NM_001367810.1; = p.R141Q on NM_014238.2) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.075); catalogued as rs199931533; called by mutect2, varscan2
- LAMA5 | c.5519A>G p.D1840G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99438539; called by muse, mutect2, varscan2
- LAMB2 | c.3532C>T p.R1178C | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765125796, COSV100025910; called by muse, varscan2
- LCK | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60739965; called by muse, mutect2, varscan2
- LCOR | c.2328G>T p.E776D | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV99616670; called by muse, mutect2
- LDB2 | c.472T>A p.W158R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100452841; called by muse, mutect2, varscan2
- LIPC | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774356974, COSV54423356, COSV54426567; called by muse, mutect2, varscan2
- LMO7 | c.2250A>T p.E750D (on ENST00000357063; = p.E431D on NM_005358.5) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100412646; called by muse, mutect2, varscan2
- LPAR3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs763826121, COSV65452856; called by muse, mutect2, varscan2
- LPO | c.2017A>G p.N673D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228516; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 17/56 reads (30%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP3 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99472053; called by muse, mutect2, varscan2
- LRRK2 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs201823680, COSV54148011; called by muse, mutect2, varscan2
- LTBP4 | c.4361C>T p.P1454L (on ENST00000308370 / NM_001042544.1; = p.P1417L on NM_003573.2) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as rs190277382, COSV99180973; called by muse, mutect2, varscan2
- LVRN | c.221G>A p.S74N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100773369; called by muse, mutect2, varscan2
- LYST | c.4204G>A p.A1402T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs199768620, COSV67706742, COSV67713902; called by muse, mutect2
- LZTS3 | c.542dup p.Q182Afs*7 | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | catalogued as rs745647523; called by mutect2, pindel, varscan2
- MACO1 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs752439249; called by mutect2, varscan2
- MACO1 | c.1280A>T p.Q427L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100975047; called by mutect2, varscan2
- MAGEA6 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.159); catalogued as COSV100262713; called by muse, mutect2, varscan2
- MAML2 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs781570943, COSV101594042; called by muse, mutect2, varscan2
- MAN2A2 | c.1582del p.X528_splice | Splice Site (DEL) | VAF 21/66 reads (32%) | catalogued as rs1219552862; called by mutect2, pindel, varscan2
- MAP3K1 | c.1738A>T p.R580* | Nonsense Mutation (SNP) | VAF 16/40 reads (40%) | catalogued as COSV101266380; called by muse, mutect2, varscan2
- MAPK15 | c.1460T>C p.V487A | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as rs1312621650, COSV100567733; called by muse, mutect2, varscan2
- MAPRE2 | c.604A>G p.T202A | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.264); catalogued as COSV100290364; called by muse, mutect2, varscan2
- MARK4 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760897998, COSV99487977; called by muse, mutect2, varscan2
- MAST3 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV53225432; called by muse, mutect2, varscan2
- MBTPS1 | c.925G>A p.G309S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58569876; called by muse, mutect2, varscan2
- MDP1 | c.128A>T p.Q43L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV99164599; called by muse, mutect2, varscan2
- MEA1 | c.62_64del p.G21del | In Frame Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs749948541; called by pindel, varscan2
- MED14 | c.4061C>T p.T1354M | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100247377; called by muse, mutect2, varscan2
- MED23 | c.2810T>A p.L937H | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); catalogued as COSV100644817; called by muse, mutect2, varscan2
- MED23 | c.570_571del p.Y191Sfs*2 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as rs1562403745; called by mutect2, pindel, varscan2
- MEF2C | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100424796; called by muse, mutect2, varscan2
- MEGF8 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as rs375853163; called by muse, mutect2, varscan2
- MEGF8 | c.1364T>C p.V455A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99234908; called by muse, mutect2, varscan2
- MICU2 | c.231A>G p.I77M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101212413; called by muse, mutect2, varscan2
- MIDEAS | c.1844C>T p.A615V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.709); catalogued as rs750351777, COSV54092674; called by muse, mutect2, varscan2
- MINK1 | c.3208A>G p.N1070D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99544628; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs750307488; called by mutect2, varscan2
- MIXL1 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100830802; called by muse, mutect2, varscan2
- MMP11 | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs62642531, COSV53156887; called by muse, mutect2, varscan2
- MMP24 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs760553975, COSV99863692; called by muse, mutect2, varscan2
- MMRN1 | c.2646del p.G883Afs*3 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | catalogued as rs750319971; called by mutect2, pindel, varscan2
- MNDA | c.164dup p.F56Vfs*21 | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | catalogued as rs750084919; called by mutect2, varscan2
- MOSPD1 | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as COSV100887818; called by muse, mutect2, varscan2
- MPP2 | c.749G>A p.R250H (on ENST00000461854 / NM_001278372.2; = p.R226H on NM_005374.5) | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.648); catalogued as rs543947750, COSV99290104; called by muse, mutect2, varscan2
- MPP7 | c.1723C>A p.H575N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100517075; called by muse, mutect2, varscan2
- MRC2 | c.4085G>A p.S1362N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100315915; called by muse, mutect2, varscan2
- MRGPRX4 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100049663; called by muse, mutect2
- MTMR14 | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99931152; called by muse, mutect2, varscan2
- MTMR3 | c.3532C>A p.L1178I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.621); catalogued as COSV100070540; called by muse, mutect2, varscan2
- MTUS1 | c.3748G>A p.A1250T (on ENST00000262102 / NM_001363061.1; = p.A416T on NM_020749.4) | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs779300410, COSV99286208; called by muse, mutect2, varscan2
- MUC5B | c.3817G>A p.V1273I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs767928303, COSV101500087; called by muse, mutect2, varscan2
- MYCBP | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV100883805; called by muse, mutect2, varscan2
- MYH10 | c.2491C>T p.H831Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV99344421; called by muse, mutect2, varscan2
- MYH13 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV99352730; called by muse, mutect2, varscan2
- MYH15 | c.5583G>T p.E1861D | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99842571; called by muse, mutect2, varscan2
- MYLK | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.018); catalogued as COSV100658629; called by muse, mutect2, varscan2
- MYO15A | c.8047G>T p.G2683C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV99231561; called by muse, mutect2
- NALCN | c.3038G>T p.G1013V | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99213451; called by muse, mutect2, varscan2
- NAT14 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99219839; called by mutect2, varscan2
- NAV1 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV99818386; called by muse, mutect2, varscan2
- NCEH1 | c.1304G>A p.R435Q (on ENST00000538775; = p.R395Q on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as rs569093474, COSV99859896; called by muse, mutect2, varscan2
- NDUFA1 | c.98del p.G33Afs*15 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | catalogued as CM091572, COSV65098058; called by mutect2, pindel, varscan2
- NEB | c.9322G>A p.V3108M | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs768110542, COSV99416769; called by muse, mutect2, varscan2
- NEBL | c.2374dup p.T792Nfs*31 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | catalogued as rs1564345967; called by mutect2, pindel, varscan2
- NEFH | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs139580489; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- NEK10 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200401044; called by muse, mutect2, varscan2
- NELFE | c.1018A>G p.T340A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100963786; called by muse, mutect2, varscan2
- NES | c.1066C>A p.L356I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV100957783; called by muse, mutect2, varscan2
- NEUROG3 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs1346375997, COSV99653445; called by muse, mutect2
- NFRKB | c.3580C>T p.P1194S (on ENST00000446488 / NM_001143835.2; = p.P1219S on NM_006165.3) | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.355); catalogued as COSV100451815; called by muse, mutect2, varscan2
- NIBAN3 | c.475C>T p.R159* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV56315156; called by muse, mutect2, varscan2
- NLRP6 | c.2017C>T p.R673W | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs142913074, COSV100380908; called by muse, mutect2, varscan2
- NOTCH2 | c.1660T>C p.Y554H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99863112; called by muse, mutect2, varscan2
- NOTCH2 | c.151T>C p.C51R | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99863113; called by muse, mutect2, varscan2
- NOTCH3 | c.4696G>A p.E1566K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.125); catalogued as COSV54650006; called by muse, mutect2, varscan2
- NOTCH3 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM023651, CM125156, COSV99656252; called by muse, mutect2, varscan2
- NPHP4 | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as COSV65393640; called by muse, mutect2
- NRG2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99179973; called by muse, mutect2, varscan2
- NSD1 | c.6112A>G p.T2038A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100728571, COSV100729644; called by muse, mutect2, varscan2
- NUP133 | c.2199+2T>C p.X733_splice | Splice Site (SNP) | VAF 10/92 reads (11%) | catalogued as COSV99772654; called by muse, mutect2, varscan2
- NUP210L | c.5269G>A p.V1757I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV99667427; called by muse, mutect2, varscan2
- NUP93 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1339514575, COSV100359992; called by muse, mutect2, varscan2
- NXPH2 | c.520del p.Q174Sfs*107 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs1558909514, COSV55642935; called by mutect2, pindel, varscan2
- NYAP2 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs551352616, COSV55999744; called by muse, mutect2, varscan2
- ONECUT1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100009065; called by muse, mutect2, varscan2
- OPRL1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61092330, COSV61092832; called by muse, mutect2, varscan2
- OR10W1 | c.489G>T p.Q163H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV101223623; called by muse, mutect2, varscan2
- OR52D1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs780502302, COSV100495159; called by muse, mutect2, varscan2
- OR5D18 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100450565; called by muse, mutect2, varscan2
- OR5H6 | c.811del p.L271Sfs*18 (on ENST00000642105; = p.L255Sfs*18 on NM_001005479.2) | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs765529082, COSV67352010; called by mutect2, pindel, varscan2
- OSMR | c.782C>T p.T261M | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs371267287; called by muse, mutect2, varscan2
- OTOF | c.4122G>T p.K1374N (on ENST00000272371 / NM_194248.3; = p.K607N on NM_004802.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.146); catalogued as COSV99716577, COSV99716841; called by muse, mutect2, varscan2
- OTOL1 | c.784A>G p.K262E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as rs575465966, COSV100019797; called by muse, varscan2
- PACS1 | c.1783T>C p.S595P | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV100269659; called by muse, mutect2, varscan2
- PAPPA2 | c.5055del p.S1686Vfs*4 | Frame Shift Del (DEL) | VAF 26/146 reads (18%) | catalogued as rs747970462, COSV62809272; called by mutect2, pindel, varscan2
- PCDH17 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1225886813, COSV64977246; called by muse, mutect2, varscan2
- PCDHA10 | c.1601T>C p.V534A | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100248472, COSV56505887; called by muse, mutect2, varscan2
- PCDHB14 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99505636; called by muse, mutect2, varscan2
- PCDHB5 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs61745762, COSV50660611; called by muse, mutect2, varscan2
- PCDHGA8 | c.2417A>G p.H806R | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV99533107; called by muse, mutect2, varscan2
- PCLO | c.4867G>A p.A1623T | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.242); catalogued as rs866989104, COSV100428654; called by muse, mutect2, varscan2
- PCNT | c.4180del p.E1394Rfs*21 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as rs755265991; called by mutect2, pindel, varscan2
- PCSK9 | c.1455C>A p.S485R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.694); catalogued as rs148683687; called by muse, mutect2, varscan2
- PDE4DIP | c.742del p.I248Sfs*18 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as rs781818141; called by mutect2, pindel, varscan2
- PDPR | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs372542476; called by muse, mutect2, varscan2
- PEAK1 | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs770000942, COSV56930966; called by muse, mutect2, varscan2
- PFKP | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV101127025; called by muse, mutect2, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs770560794; called by mutect2, varscan2
- PHC2 | c.730C>T p.Q244* | Nonsense Mutation (SNP) | VAF 51/104 reads (49%) | catalogued as COSV99930781; called by muse, mutect2, varscan2
- PHEX | c.664C>T p.L222= | Splice Region (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101039468; called by muse, mutect2, varscan2
- PHF20L1 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.522); catalogued as COSV99620170, COSV99620618; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs756552559; called by mutect2, varscan2
- PIK3R5 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV99353006; called by muse, mutect2, varscan2
- PIP5K1C | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.539); catalogued as rs762902576, COSV100095098, COSV58951776; called by muse, mutect2, varscan2
- PIP5K1C | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV100095101; called by muse, mutect2, varscan2
- PJA2 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.283); catalogued as COSV100754332; called by muse, mutect2, varscan2
- PKD1L2 | c.218G>A p.W73* | Nonsense Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as rs769977034, COSV100449667; called by muse, mutect2, varscan2
- PKD2L2 | c.910del p.I304* | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | catalogued as rs758905083; called by mutect2, pindel, varscan2
- PKHD1 | c.2090C>T p.T697M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs377415956; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PKP1 | c.2036A>C p.Y679S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV99824990; called by muse, mutect2, varscan2
- PKP3 | c.1279C>A p.L427M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs779964513, COSV100520743; called by muse, mutect2, varscan2
- PLA2G2A | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs142941380; called by muse, mutect2, varscan2
- PLA2R1 | c.4119del p.G1374Afs*32 | Frame Shift Del (DEL) | VAF 28/71 reads (39%) | catalogued as rs746999253; called by mutect2, varscan2
- PLCL2 | c.1907C>T p.S636L (on ENST00000615277 / NM_001144382.2; = p.S510L on NM_015184.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV101196606; called by muse, mutect2, varscan2
- PLD2 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558449929, COSV99562103; called by muse, mutect2, varscan2
- PLIN4 | c.2633C>T p.T878I (on ENST00000301286; = p.T893I on NM_001367868.2) | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.661); catalogued as rs1217794828, COSV100012854; called by muse, mutect2, varscan2
- PLVAP | c.413T>C p.L138S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1365130004, COSV99391536; called by muse, mutect2, varscan2
- PLXNA3 | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as rs782309256, COSV63754150; called by muse, mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PMS2 | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99763956; called by muse, mutect2, varscan2
- PNPLA7 | c.2944C>T p.R982W | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779068396, COSV99480283; called by muse, mutect2, varscan2
- POLE | c.2291G>T p.R764M | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100265647; called by muse, mutect2, varscan2
- POLR3E | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs760383677, COSV55402016; called by muse, mutect2, varscan2
- POLR3H | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1235087074, COSV99347109; called by muse, mutect2, varscan2
- POMGNT1 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 3/25 reads (12%) | PolyPhen probably damaging (0.972); catalogued as COSV100915431; called by muse, mutect2
- POR | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1222031035, COSV101203496; called by muse, mutect2, varscan2
- PPL | c.3386A>T p.E1129V | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1456575414, COSV99277609; called by muse, mutect2, varscan2
- PPP1R15B | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as rs576266765, COSV100916305; called by muse, mutect2, varscan2
- PPP1R1B | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as COSV99566122; called by muse, mutect2, varscan2
- PPP1R32 | c.943A>G p.K315E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.037); catalogued as rs1292496425, COSV58545076; called by muse, mutect2, varscan2
- PPP5C | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs1260657606, COSV50139728; called by muse, mutect2, varscan2
- PPP6R3 | c.602C>A p.P201Q | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99675837; called by muse, mutect2, varscan2
- PRDM1 | c.2000A>G p.K667R | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.444); catalogued as rs375041438; called by muse, mutect2, varscan2
- PRDM16 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV99575814; called by muse, mutect2, varscan2
- PRDX3 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100045321; called by muse, mutect2, varscan2
- PRF1 | c.808G>A p.G270S | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.182); catalogued as rs143043887; called by muse, mutect2, varscan2
- PROP1 | c.175C>T p.Q59* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100383646; called by muse, mutect2, varscan2
- PRRC2C | c.5602T>C p.S1868P (on ENST00000367742; = p.S1866P on NM_015172.4) | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV100144839; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 19/48 reads (40%) | catalogued as rs781858060; called by mutect2, varscan2
- PRUNE1 | c.519T>C p.H173= | Splice Region (SNP) | VAF 20/72 reads (28%) | catalogued as COSV99639316; called by muse, mutect2, varscan2
- PRX | c.4153G>A p.A1385T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99396447; called by mutect2, varscan2
- PSME3IP1 | c.104T>C p.V35A | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100483660; called by muse, mutect2, varscan2
- PTBP1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as COSV100608422; called by muse, mutect2, varscan2
- PTCH2 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.153); catalogued as rs745322399, COSV100941959; called by muse, mutect2, varscan2
- PTCHD4 | c.2333C>T p.S778L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1223923077, COSV59779920; called by muse, mutect2, varscan2
- PTEN | c.681del p.N228Ifs*28 | Frame Shift Del (DEL) | VAF 66/100 reads (66%) | catalogued as COSV64294248; called by mutect2, pindel, varscan2
- PTHLH | c.391G>A p.G131R | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV52369175; called by muse, mutect2, varscan2
- PTPN18 | c.1315+1G>A p.X439_splice | Splice Site (SNP) | VAF 16/36 reads (44%) | catalogued as rs780094184, COSV99447511; called by muse, mutect2, varscan2
- PTPN21 | c.2857G>A p.A953T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs112928496, COSV60850408; called by muse, mutect2, varscan2
- PTPN21 | c.2545del p.I849Lfs*9 | Frame Shift Del (DEL) | VAF 46/112 reads (41%) | catalogued as rs778292578; called by mutect2, varscan2
- PTPN6 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs1177433416, COSV100016973; called by muse, mutect2, varscan2
- RAB24 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100293484; called by muse, mutect2, varscan2
- RAB43 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs770560786, COSV59349363; called by muse, mutect2, varscan2
- RABGAP1L | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1164289432, COSV52303790; called by muse, mutect2, varscan2
- RAD54L2 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs866927120, COSV56577948; called by muse, mutect2, varscan2
- RANBP1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59334471; called by muse, mutect2, varscan2
- RANBP2 | c.8027A>G p.D2676G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1203383987, COSV99311483; called by muse, mutect2, varscan2
- RASAL2 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs546030844, COSV62724691; called by muse, mutect2, varscan2
- RASGEF1B | c.967del p.T323Lfs*5 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs765006689; called by mutect2, varscan2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs781825075; called by mutect2, varscan2
- RBM22 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs753286282, COSV99555940; called by muse, varscan2
- RCAN3 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100980322; called by muse, mutect2, varscan2
- RECQL4 | c.3206G>A p.R1069H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs752847936, COSV100020329; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REEP1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1351359618, COSV51257608; called by muse, mutect2, varscan2
- RGL1 | c.842C>A p.S281Y (on ENST00000360851 / NM_001297672.2; = p.S316Y on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100486295; called by muse, mutect2, varscan2
- RGS14 | c.1697T>G p.L566R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.08); catalogued as COSV101281702; called by muse, mutect2, varscan2
- RHOXF2B | c.169G>T p.G57* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV101003948; called by mutect2, varscan2
- RIMBP3 | c.3296C>T p.S1099L | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs1486195288; called by muse, varscan2
- RNF123 | c.1285G>A p.V429M | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs759277592, COSV100570354; called by muse, mutect2
- RNF139 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.145); catalogued as rs770207318, COSV52681794; called by muse, mutect2, varscan2
- RNF139 | c.1788G>T p.K596N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs139815535; called by muse, varscan2
- RNF151 | c.223A>C p.T75P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100364340; called by muse, mutect2, varscan2
- RNF17 | c.1877C>A p.P626Q | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99692482; called by muse, mutect2, varscan2
- RNF175 | c.74A>G p.H25R | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.124); catalogued as COSV99923950; called by muse, mutect2, varscan2
- RNF2 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1190450163, COSV100835673; called by muse, mutect2, varscan2
- RPAP1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.163); catalogued as COSV100426994; called by muse, mutect2, varscan2
- RPIA | c.343A>C p.I115L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV99375947; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KC1 | c.2881G>A p.D961N | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV100873797, COSV100874115; called by muse, mutect2, varscan2
- RPS6KL1 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100665002; called by muse, mutect2, varscan2
- RREB1 | c.3944C>T p.T1315M | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375377458; called by muse, mutect2, varscan2
- RTN4R | c.1082G>C p.G361A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as COSV99244880; called by muse, mutect2, varscan2
- RYR1 | c.5083C>T p.H1695Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100614920, COSV62103370; called by muse, mutect2, varscan2
- SACS | c.9305del p.L3102* | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as COSV66537749; called by pindel, varscan2
- SBSN | c.1756G>A p.A586T (on ENST00000452271 / NM_001166034.2; = p.A243T on NM_198538.4) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs370367137, COSV71733144; called by muse, mutect2, varscan2
- SCN3A | c.4925G>A p.R1642H | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1433107678, COSV51829056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.3298C>T p.L1100F | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101438358; called by muse, mutect2, varscan2
- SCN5A | c.287T>C p.L96P | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100028278; called by muse, mutect2, varscan2
- SDE2 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1203818554, COSV99682525; called by muse, mutect2, varscan2
- SDS | c.471G>T p.W157C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99980973; called by muse, mutect2, varscan2
- SEMA4F | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100335811; called by muse, mutect2, varscan2
- SENP1 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs764220197, COSV99136818; called by muse, mutect2, varscan2
- SESN1 | c.601C>T p.H201Y (on ENST00000356644 / NM_001199933.1; = p.H260Y on NM_014454.3) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); catalogued as COSV100122709; called by muse, mutect2
- SETD5 | c.4249C>T p.R1417C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs747372821, COSV100200286, COSV100200600; called by muse, mutect2, varscan2
- SETDB1 | c.3659G>A p.R1220H | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54978004; called by muse, mutect2, varscan2
- SETX | c.6663G>T p.Q2221H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56386250; called by muse, mutect2, varscan2
- SHANK2 | c.2236A>G p.T746A | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.157); catalogued as COSV99572686; called by muse, mutect2, varscan2
- SIMC1 | c.976T>G p.S326A (on ENST00000443967 / NM_001308196.1; = p.S345A on NM_001308195.2) | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.375); catalogued as rs748838527, COSV100365290; called by muse, mutect2, varscan2
- SLA | c.252G>A p.W84* (on ENST00000338087 / NM_001045556.3; = p.W124* on NM_006748.4) | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99599543; called by muse, mutect2, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 30/153 reads (20%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC12A1 | c.93G>T p.E31D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100372239; called by muse, varscan2
- SLC12A8 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs373665310; called by muse, mutect2, varscan2
- SLC16A1 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as rs577209023, COSV63708911; called by muse, mutect2, varscan2
- SLC20A2 | c.1039G>A p.V347M | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV60601880, COSV60602651; called by muse, mutect2, varscan2
- SLC25A10 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751198747, COSV58970770; called by muse, mutect2, varscan2
- SLC2A4 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV99142660; called by muse, mutect2, varscan2
- SLC36A3 | c.1049C>G p.A350G | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV100077423; called by muse, mutect2
- SLC41A1 | c.871G>A p.V291M | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV100900347; called by muse, mutect2
- SLC44A3 | c.278del p.K93Nfs*6 (on ENST00000271227 / NM_001114106.3; = p.K45Nfs*6 on NM_152369.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs748117099; called by pindel, varscan2
- SLC45A4 | c.2277G>T p.Q759H (on ENST00000517878 / NM_001286646.2; = p.Q708H on NM_001080431.2) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99196671; called by mutect2, varscan2
- SLC47A1 | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99565138; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs759883814, COSV56092392; called by mutect2, varscan2
- SLC7A2 | c.1056-1G>T p.X352_splice | Splice Site (SNP) | VAF 26/51 reads (51%) | catalogued as COSV99134441; called by muse, mutect2, varscan2
- SLC7A9 | c.562G>A p.V188M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as rs531029519, CD024465, CM050100, COSV50083364; called by muse, mutect2
- SLC9C2 | c.2243G>A p.G748D | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100876613; called by muse, mutect2, varscan2
- SLC9C2 | c.597dup p.G200Wfs*14 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | catalogued as rs760633653; called by mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 24/32 reads (75%) | catalogued as rs763364024; called by mutect2, varscan2
- SMARCAL1 | c.2003G>T p.R668L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs759292582, COSV100619815, COSV61921196; called by muse, mutect2, varscan2
- SMARCC2 | c.2551C>T p.R851W | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1171843395, COSV57214908; called by muse, mutect2, varscan2
- SMURF2 | c.91+1G>A p.X31_splice | Splice Site (SNP) | VAF 17/40 reads (43%) | catalogued as rs1555689073, COSV52320351; called by muse, mutect2, varscan2
- SNCG | c.316del p.Q106Nfs*53 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | catalogued as rs1331418216; called by mutect2, pindel, varscan2
- SNRNP200 | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs925487616, COSV100107296; called by muse, mutect2, varscan2
- SNRNP70 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV99672206; called by muse, mutect2, varscan2
- SNRPE | c.224-2A>G p.X75_splice | Splice Site (SNP) | VAF 54/258 reads (21%) | catalogued as COSV100919275; called by muse, mutect2, varscan2
- SP100 | c.26G>A p.S9N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1410615043, COSV99892547; called by muse, mutect2, varscan2
- SP140 | c.2227C>T p.Q743* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100613497; called by muse, mutect2, varscan2
- SP140L | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as COSV99706833; called by muse, mutect2, varscan2
- SPAG17 | c.282del p.K94Nfs*3 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | catalogued as rs771461785; called by mutect2, pindel, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 7/10 reads (70%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPEG | c.9016C>T p.R3006W | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs781096883, COSV56663392; called by muse, mutect2, varscan2
- SPEN | c.6313del p.A2105Lfs*33 | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | catalogued as COSV65367511; called by mutect2, pindel
- SPHKAP | c.2744C>T p.T915M | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs373462091, COSV60878125; called by muse, mutect2, varscan2
- SPIB | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs887253633, COSV54529461; called by muse, mutect2, varscan2
- SPTAN1 | c.6389G>A p.R2130H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs373259652, COSV100823322; called by muse, varscan2
- SPTB | c.5770C>T p.R1924W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs764617663, COSV101072006; called by muse, mutect2, varscan2
- SPTB | c.1108C>T p.Q370* | Nonsense Mutation (SNP) | VAF 52/103 reads (50%) | catalogued as COSV101072007; called by muse, mutect2, varscan2
- STAB2 | c.39G>T p.L13F | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs140037467; called by muse, mutect2, varscan2
- STAP2 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs752401379, COSV55696574, COSV99696647; called by muse, mutect2, varscan2
- STARD8 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200556349, COSV52925468; called by muse, mutect2, varscan2
- STIL | c.2616-2A>C p.X872_splice | Splice Site (SNP) | VAF 23/47 reads (49%) | catalogued as COSV99680673; called by muse, mutect2, varscan2
- STK26 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100688589; called by muse, mutect2, varscan2
- STK26 | c.518A>G p.Q173R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.304); catalogued as COSV100688590; called by muse, mutect2, varscan2
- STN1 | c.757A>C p.N253H | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV99830131; called by muse, varscan2
- STOML1 | c.140C>A p.P47H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV51455749, COSV99166749; called by muse, mutect2, varscan2
- STON2 | c.893G>A p.S298N (on ENST00000649389 / NM_001366849.2; = p.S241N on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as rs1367324943, COSV99964483; called by muse, mutect2, varscan2
- SUGP2 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100431307; called by muse, mutect2, varscan2
- SVEP1 | c.1181G>A p.C394Y | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237482; called by muse, mutect2, varscan2
- SYMPK | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV99841465; called by muse, mutect2, varscan2
- SYNE1 | c.21803C>T p.A7268V (on ENST00000367255 / NM_182961.4; = p.A7197V on NM_033071.3) | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV99556157; called by muse, mutect2, varscan2
- TASOR2 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100050072; called by muse, mutect2, varscan2
- TBC1D8 | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.556); catalogued as rs947243198, COSV100964315; called by muse, mutect2, varscan2
- TBC1D9B | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs138071086; called by muse, mutect2, varscan2
- TBL2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.867); catalogued as COSV99979526; called by muse, mutect2, varscan2
- TBX21 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs1229594657, COSV99455901; called by muse, mutect2, varscan2
- TCERG1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); catalogued as rs930771968, COSV57038424; called by muse, mutect2, varscan2
- TCF20 | c.3479C>A p.A1160D | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); catalogued as COSV100166357; called by muse, mutect2, varscan2
- TDRD10 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs781605784, COSV52724407; called by muse, mutect2
- TET1 | c.65dup p.K23Efs*37 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | catalogued as rs1196853334; called by mutect2, varscan2
- TEX2 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1312121433, COSV51982196; called by muse, mutect2, varscan2
- TGFBR1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66625946; called by muse, mutect2, varscan2
- TGS1 | c.1789C>T p.P597S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99485163; called by muse, mutect2, varscan2
- THOP1 | c.486+1G>C p.X162_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100310422; called by muse, mutect2, varscan2
- TICAM1 | c.1903G>A p.A635T | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs780241594, COSV99941024; called by muse, mutect2, varscan2
- TLE1 | c.1600C>A p.R534S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100918842, COSV64720352; called by muse, mutect2, varscan2
- TMEM109 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV50005340; called by muse, mutect2, varscan2
- TMEM139 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs202131612, COSV60081687; called by muse, mutect2, varscan2
- TMEM175 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99297592; called by muse, mutect2, varscan2
- TMEM184A | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs752747053, COSV99867937; called by muse, varscan2
- TMEM243 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375982092; called by muse, mutect2, varscan2
- TMEM45A | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 41/103 reads (40%) | catalogued as COSV100058179; called by muse, mutect2, varscan2
- TMEM94 | c.2876G>T p.R959L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100050194, COSV58592865; called by muse, mutect2, varscan2
- TMPRSS3 | c.169A>G p.I57V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.06); catalogued as COSV99367715; called by muse, mutect2, varscan2
- TNFAIP3 | c.110T>G p.I37S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99396431; called by muse, mutect2, varscan2
- TNFRSF11B | c.328G>A p.G110R | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99816479; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNPO3 | c.1316C>A p.A439E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV99602552; called by muse, mutect2, varscan2
- TNS3 | c.2358del p.Q787Sfs*33 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | catalogued as COSV60787512; called by mutect2, pindel, varscan2
- TNS3 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100235031; called by muse, mutect2, varscan2
- TNXB | c.4738C>T p.R1580C (on ENST00000647633; = p.R1333C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); catalogued as rs775418163, COSV64483436; called by muse, mutect2, varscan2
- TONSL | c.1879C>T p.R627C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs751754276, COSV101340160; called by muse, mutect2, varscan2
- TPH1 | c.1117T>C p.Y373H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000704; called by muse, mutect2, varscan2
- TRBJ2-1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as rs1313793338; called by muse, mutect2, varscan2
- TRIM22 | c.1133T>C p.L378P | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66091101; called by muse, mutect2, varscan2
- TRIM26 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV101443919; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIM60 | c.1133A>C p.Q378P | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100593939; called by muse, mutect2, varscan2
- TRIM71 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV67470367; called by muse, mutect2, varscan2
- TRO | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV99435946; called by muse, mutect2, varscan2
- TRPM2 | c.2827G>A p.V943M | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100308328; called by muse, mutect2, varscan2
- TRRAP | c.7573A>G p.I2525V (on ENST00000359863 / NM_001244580.1; = p.I2507V on NM_003496.3) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV100722156; called by muse, mutect2, varscan2
- TSNAXIP1 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV54649888; called by muse, mutect2, varscan2
- TTBK1 | c.2818A>G p.N940D | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99443966; called by muse, mutect2, varscan2
- TTI1 | c.1163T>C p.L388P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100989594; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTLL8 | c.440A>G p.H147R | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.878); catalogued as COSV99838101; called by muse, mutect2, varscan2
- TTN | c.1591A>G p.K531E | Missense Mutation (SNP) | VAF 21/59 reads (36%) | PolyPhen benign (0.275); catalogued as COSV100599261; called by muse, mutect2, varscan2
- UBASH3B | c.660A>C p.Q220H | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99417043; called by muse, mutect2, varscan2
- UBE2J2 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214697037, COSV100231075; called by muse, mutect2, varscan2
- UBQLN4 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 34/179 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.054); catalogued as COSV100849074; called by muse, mutect2, varscan2
- UBR4 | c.6719G>A p.R2240H | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100920515, COSV104427136; called by muse, mutect2, varscan2
- UGT1A10 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV100761436; called by muse, mutect2, varscan2
- UPF3B | c.1102C>T p.R368W (on ENST00000276201 / NM_080632.3; = p.R355W on NM_023010.3) | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); catalogued as rs374676402, COSV52230481; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | catalogued as rs747493460; called by mutect2, varscan2
- USHBP1 | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV53104138, COSV99394063; called by muse, mutect2, varscan2
- UTRN | c.9439C>A p.P3147T | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100837816; called by muse, mutect2, varscan2
- UVRAG | c.420C>A p.Y140* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100638231; called by muse, varscan2
- VCP | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100734140; called by muse, mutect2, varscan2
- VPS13C | c.11100del p.D3701Tfs*13 (on ENST00000644861 / NM_020821.3; = p.D3658Tfs*13 on NM_017684.5) | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as COSV99830887; called by mutect2, pindel, varscan2
- VPS53 | c.1510T>A p.Y504N (on ENST00000571805 / NM_001366253.2; = p.Y475N on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.675); catalogued as COSV99345548; called by muse, mutect2, varscan2
- VSX2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV100001514; called by muse, mutect2, varscan2
- VSX2 | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100001517; called by muse, mutect2, varscan2
- VTCN1 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100061497; called by muse, mutect2, varscan2
- VWA3B | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV101345962; called by muse, mutect2, varscan2
- VWF | c.6610C>A p.P2204T | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99778347; called by muse, mutect2, varscan2
- VWF | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs181452677, COSV54610591; called by muse, varscan2
- WASHC4 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs1447144583, COSV59888338, COSV59890135; called by muse, mutect2, varscan2
- WDR54 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99269398; called by muse, varscan2
- WDR59 | c.534+1G>A p.X178_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as rs1275107529, COSV100049031; called by muse, mutect2, varscan2
- WDR88 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs575618079, COSV63452886; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 26/31 reads (84%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIZ | c.2561C>A p.P854H (on ENST00000673675 / NM_001371589.1; = p.P117H on NM_021241.3) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99652776; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XIAP | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.851); catalogued as rs147946593, COSV63023924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XPOT | c.2750A>G p.Q917R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100225386; called by muse, mutect2, varscan2
- YPEL1 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1408603721, COSV100256173; called by muse, mutect2, varscan2
- YY1 | c.690del p.D231Ifs*25 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | catalogued as rs759536629; called by mutect2, varscan2
- ZBED1 | c.669del p.N224Tfs*10 | Frame Shift Del (DEL) | VAF 25/65 reads (38%) | catalogued as COSV100585979; called by mutect2, pindel, varscan2
- ZBTB7C | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as COSV100134291; called by muse, mutect2, varscan2
- ZC3H12A | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100897659; called by muse, mutect2, varscan2
- ZC3H18 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.102); catalogued as COSV56326307; called by muse, mutect2, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs751577786; called by mutect2, varscan2
- ZC3H18 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1218820465, COSV56322450; called by muse, mutect2
- ZCRB1 | c.552del p.K184Nfs*20 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs751992496; called by mutect2, varscan2
- ZFHX3 | c.6347del p.P2116Rfs*60 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | catalogued as COSV104391232; called by mutect2, pindel, varscan2
- ZFHX4 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs778328088, COSV51449679; called by muse, mutect2, varscan2
- ZFHX4 | c.10633C>T p.P3545S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.357); catalogued as COSV51494272, COSV51498611; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2072del p.N691Mfs*12 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs556762260; called by pindel, varscan2
- ZMAT1 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100858706, COSV65658019; called by muse, mutect2, varscan2
- ZNF175 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1390497187, COSV99219318; called by muse, mutect2
- ZNF229 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.037); catalogued as rs750062758, COSV52162067; called by muse, mutect2, varscan2
- ZNF236 | c.1381del p.M461* | Frame Shift Del (DEL) | VAF 15/24 reads (63%) | catalogued as rs769237443, COSV53487827; called by mutect2, varscan2
- ZNF250 | c.1415T>C p.I472T | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.597); catalogued as COSV99480710; called by muse, mutect2, varscan2
- ZNF275 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs1009182083, COSV100936182, COSV64704772; called by muse, mutect2, varscan2
- ZNF280C | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs770032114, COSV100921199; called by muse, mutect2, varscan2
- ZNF281 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs1437058317, COSV54166846; called by muse, mutect2
- ZNF300 | c.1133A>G p.E378G | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51033424, COSV99199808; called by muse, mutect2, varscan2
- ZNF337 | c.1725G>T p.K575N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.027); catalogued as COSV99430066; called by muse, mutect2, varscan2
- ZNF33A | c.1721A>G p.H574R (on ENST00000458705 / NM_006974.3; = p.H575R on NM_006954.2) | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100275586; called by muse, mutect2, varscan2
- ZNF441 | c.1021T>C p.C341R | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751011175, COSV100777404; called by muse, mutect2, varscan2
- ZNF442 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs759593423, COSV54422875; called by muse, mutect2, varscan2
- ZNF479 | c.381del p.K127Nfs*74 | Frame Shift Del (DEL) | VAF 48/117 reads (41%) | catalogued as rs782331095; called by mutect2, pindel, varscan2
- ZNF571 | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV100143573; called by muse, mutect2, varscan2
- ZNF687 | c.2197dup p.H733Pfs*5 | Frame Shift Ins (INS) | VAF 18/95 reads (19%) | catalogued as rs763747864; called by mutect2, varscan2
- ZNF71 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.679); catalogued as COSV100045695; called by muse, mutect2, varscan2
- ZNF721 | c.2111G>A p.R704K (on ENST00000338977; = p.R716K on NM_133474.4) | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs782103258, COSV100167146; called by muse, mutect2, varscan2
- ZNF74 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 31/57 reads (54%) | catalogued as COSV100677439; called by muse, mutect2, varscan2
- ZNF778 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100124330; called by muse, mutect2, varscan2
- ZNFX1 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as rs1334545609, COSV100870767; called by muse, mutect2, varscan2
- ZRANB1 | c.*9del | Frame Shift Del (DEL) | VAF 15/30 reads (50%) | catalogued as rs535580590; called by mutect2, varscan2
- ZSCAN10 | c.1451C>T p.A484V (on ENST00000252463; = p.A539V on NM_032805.3) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (0.26); PolyPhen benign (0.033); catalogued as rs1443616831, COSV52967633; called by muse, mutect2, varscan2
- ABL2 | c.2865dup p.N956Efs*2 (on ENST00000502732 / NM_007314.4; = p.N941Efs*2 on NM_005158.5) | Frame Shift Ins (INS) | VAF 50/237 reads (21%) | called by mutect2, pindel, varscan2
- AGR3 | c.172del p.S58Vfs*5 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- ALS2 | c.1874del p.L625* | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- APBB3 | c.1193del p.G398Dfs*81 (on ENST00000357560 / NM_133173.2; = p.G405Dfs*81 on NM_006051.3) | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- ARHGAP30 | c.2627_2628del p.K876Rfs*8 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by mutect2, pindel
- B4GALNT3 | c.1287_1289del p.L430del | In Frame Del (DEL) | VAF 34/84 reads (40%) | called by mutect2, pindel, varscan2
- BAAT | c.1del p.M1? | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- BICD1 | c.532_534del p.E178del | In Frame Del (DEL) | VAF 9/30 reads (30%) | called by pindel, varscan2
- BTAF1 | c.215del p.N72Mfs*30 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- C10orf120 | c.762del p.K254Nfs*3 | Frame Shift Del (DEL) | VAF 45/100 reads (45%) | called by mutect2, pindel, varscan2
- CAPN10 | c.1592del p.G531Afs*71 | Frame Shift Del (DEL) | VAF 11/17 reads (65%) | called by mutect2, varscan2
- CCDC191 | c.2497del p.C833Vfs*20 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, varscan2
- CCN6 | c.623_624del p.K208Mfs*21 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- CDC7 | c.1544del p.K515Rfs*18 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- CDH24 | c.714del p.L239Cfs*7 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- CENPF | c.8869del p.S2957Afs*6 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, varscan2
- COL14A1 | c.5378del p.G1793Afs*19 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | called by mutect2, varscan2
- COL1A2 | c.2051del p.P684Lfs*102 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- COL8A1 | c.1795del p.H599Mfs*24 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | called by mutect2, pindel, varscan2
- COL9A3 | c.196del p.A66Pfs*22 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- CYFIP2 | c.3729del p.F1243Lfs*4 (on ENST00000616178 / NM_001291722.2; = p.F1218Lfs*4 on NM_014376.4) | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | called by mutect2, pindel, varscan2
- CYTIP | c.231dup p.V78Cfs*8 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- DDX4 | c.398_400del p.Y133_R134delins* | Nonsense Mutation (DEL) | VAF 9/19 reads (47%) | called by mutect2, varscan2
- DDX53 | c.1828_1829del p.K610Efs*41 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- DENND4B | c.3263del p.P1088Qfs*42 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- DNMT1 | c.1972-3del | Splice Region (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- DOCK5 | c.2947_2949del p.I983del | In Frame Del (DEL) | VAF 13/37 reads (35%) | called by pindel, varscan2
- DYRK3 | c.905del p.N302Ifs*35 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | called by mutect2, varscan2
- EEF2 | c.721del p.E241Rfs*13 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- EIF3J | c.180del p.E61Rfs*5 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- EIF4H | c.537del p.M180Wfs*46 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | called by mutect2, pindel, varscan2
- ELF3 | c.959dup p.N321Efs*150 | Frame Shift Ins (INS) | VAF 8/30 reads (27%) | called by mutect2, varscan2
- ESRP1 | c.208del p.I70* | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- FBN2 | c.5943del p.F1981Lfs*35 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- FCGR3B | c.539del p.N180Mfs*7 | Frame Shift Del (DEL) | VAF 52/179 reads (29%) | called by mutect2, varscan2
- FN1 | c.5274del p.K1759Rfs*7 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- FRRS1 | c.370dup p.T124Nfs*4 | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- GDA | c.1251del p.F417Lfs*15 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- GTDC1 | c.906del p.F302Lfs*4 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- HDLBP | c.1769_1772del p.K590Sfs*63 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | called by mutect2, pindel, varscan2
- HEATR9 | c.691del p.R231Gfs*5 | Frame Shift Del (DEL) | VAF 34/97 reads (35%) | called by mutect2, pindel, varscan2
- HEXD | c.737_746del p.F246Cfs*47 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- IGKV3-11 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 63/144 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGSF3 | c.2997del p.R1001Gfs*34 (on ENST00000369486 / NM_001007237.3; = p.R1021Gfs*34 on NM_001542.4) | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | called by mutect2, varscan2
- IRX2 | c.434dup p.E146Rfs*44 | Frame Shift Ins (INS) | VAF 52/162 reads (32%) | called by pindel, varscan2
- JAK1 | c.1035dup p.L346Tfs*4 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- JAK1 | c.425dup p.I143Dfs*9 | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | called by mutect2, varscan2
- KIF2A | c.507del p.K169Nfs*32 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- KIF5B | c.1864del p.M622Wfs*8 | Frame Shift Del (DEL) | VAF 36/122 reads (30%) | called by mutect2, pindel, varscan2
358 further variants in this file (63 protein-altering or splice-affecting, 260 silent, 35 other) are not listed here.
